Gene-level copy-number profile of tumor specimen ALCH-B366-TTP1-A from ALCHEMIST case ALCH-B366, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.6 years (21,041 days).
Specimen ALCH-B366-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a6fe558a-029e-43a5-ae4f-6eb9f93f3e94.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B366-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/e90d5861-ce68-46e2-9216-2b0ea996ad87

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 14,363; copy number 2: 37,103; copy number 3: 7,421; copy number 4: 5; copy number 5: 2.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,985,922–89,990,221, 2 genes: IGKV2D-26, IGKV3D-25.
- chr3:46,017,007–46,027,487, 2 genes: XCR1, NRBF2P2.
- chr12:132,550,729–132,554,947, 1 gene (within-gene range 0–1): AC131212.3.
- chr15:70,848,883–70,849,770, 1 gene (within-gene range 0–2): AC009269.4.
- chr15:70,858,714–70,860,162, 1 gene (within-gene range 0–2): KRT8P9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:34,696,317–34,697,470, 1 gene, copy number 5 (within-gene range 3–5): AL451165.2.

Autosomal genes at a single copy (total copy number 1): 11,677. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
